Somatic mutation profile of tumor specimen TCGA-GL-7966-01A (aliquot TCGA-GL-7966-01A-11D-2201-08) from TCGA case TCGA-GL-7966, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 28.6 years (10,428 days).
Specimen TCGA-GL-7966-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b8286e1-7b6e-470b-88d6-9eaba863b5cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GL-7966-10A (Blood Derived Normal), aliquot TCGA-GL-7966-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ea0c937-4ed2-4548-8267-eb7fd80c9072

The open-access MAF lists 34 somatic variants for this specimen: 23 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 15, Silent 11, Frame Shift Del 5, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C11orf80 | c.380T>C p.I127T | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1299569050, COSV60928106; called by muse, mutect2
- CNOT10 | c.920G>A p.S307N | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV100094896, COSV59390640; called by muse, mutect2
- EVI5 | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV64825656; called by muse, mutect2, varscan2
- FH | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 87/199 reads (44%) | catalogued as COSV63817549; called by muse, mutect2, varscan2
- KIAA0753 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 9/153 reads (6%) | catalogued as COSV63816821; called by muse, mutect2
- KXD1 | c.467A>T p.Q156L | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV55889036, COSV55890266; called by muse, mutect2
- LSS | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 46/62 reads (74%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.563); catalogued as COSV62700038; called by muse, mutect2, varscan2
- MYCBPAP | c.2812C>T p.R938C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1347370391, COSV99276781; called by muse, mutect2
- NF2 | c.884del p.L295Rfs*14 | Frame Shift Del (DEL) | VAF 14/25 reads (56%) | catalogued as CD070492; called by mutect2, pindel, varscan2
- NUAK2 | c.761A>G p.D254G | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV65680852; called by muse, mutect2, varscan2
- SDE2 | c.276T>G p.I92M | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55249921; called by muse, mutect2, varscan2
- SERPINB10 | c.341T>A p.I114K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV53071966; called by muse, mutect2, varscan2
- SESTD1 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV58930320; called by muse, mutect2, varscan2
- SYT4 | c.658G>C p.D220H | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54898452; called by muse, mutect2, varscan2
- TRPV2 | c.2261A>G p.N754S | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV58427375; called by muse, mutect2, varscan2
- TTC25 | c.1139T>C p.I380T | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV66367555; called by muse, mutect2, varscan2
- USH2A | c.7061G>A p.R2354H | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs201386640, CM065510, COSV56331304; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZSWIM4 | c.2348C>T p.S783L | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV54319477; called by muse, mutect2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | called by pindel, varscan2
- CACNG2 | c.130del p.S44Vfs*15 | Frame Shift Del (DEL) | VAF 111/198 reads (56%) | called by mutect2, pindel, varscan2
- STARD3 | c.63_74del p.G23_L26del | In Frame Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- TAF1B | c.1374_1380del p.S458Rfs*39 | Frame Shift Del (DEL) | VAF 19/99 reads (19%) | called by mutect2, pindel, varscan2
- TCFL5 | c.904_907del p.F302Vfs*13 | Frame Shift Del (DEL) | VAF 67/195 reads (34%) | called by pindel, varscan2
- ABCB6 | c.2382C>T p.I794= | Silent (SNP) | VAF 8/123 reads (7%) | catalogued as COSV54693159, COSV54696532; called by muse, mutect2
- EIF2AK3 | c.972G>A p.K324= | Silent (SNP) | VAF 11/165 reads (7%) | catalogued as COSV57545182; called by muse, mutect2
- GLB1L2 | c.1401A>G p.T467= | Silent (SNP) | VAF 72/192 reads (38%) | catalogued as COSV60277521; called by muse, mutect2, varscan2
- MYBPC2 | c.210G>T p.V70= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV63093534; called by muse, mutect2, varscan2
- OR6Y1 | c.393T>A p.I131= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV56928268; called by muse, mutect2
- SCN2A | c.2760C>G p.L920= | Silent (SNP) | VAF 25/172 reads (15%) | catalogued as COSV51833224; called by muse, mutect2, varscan2
- SHROOM1 | c.714G>A p.P238= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs758837191, COSV60580557; called by muse, mutect2, varscan2
- TAS2R1 | c.771C>T p.F257= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV66778196; called by muse, mutect2
- UACA | c.234G>A p.K78= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as COSV59853472; called by muse, mutect2, varscan2
- ULK1 | c.900C>T p.S300= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as rs571147302, COSV58854749; called by muse, mutect2, varscan2
- XIRP2 | c.7332G>A p.R2444= (on ENST00000628543; = p.R2619= on NM_152381.6) | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as COSV54684116; called by muse, mutect2, varscan2
